Somatic mutation profile of tumor specimen MMRF_1823_1_BM_CD138pos (aliquot MMRF_1823_1_BM_CD138pos_T1_KBS5U_K11319) from MMRF case MMRF_1823, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.2 years (18,708 days).
Specimen MMRF_1823_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bbef0c4-d178-4283-af9b-410ea4107036.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1823_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1823_1_PB_Whole_C2_KBS5U_K11320; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89d6f3e9-1e9c-4d7a-bbbb-9ae5c9748468

The open-access MAF lists 138 somatic variants for this specimen: 62 protein-altering or splice-affecting, 14 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, 3'UTR 33, Intron 20, Silent 14, 5'UTR 4, 3'Flank 3, Frame Shift Del 2, In Frame Ins 1, Frame Shift Ins 1, RNA 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 94/212 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AK2 | c.431G>A p.R144H (on ENST00000354858; = p.R186H on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs754485826, COSV61470625; called by muse, varscan2
- ARID4A | c.3145T>C p.F1049L | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1210036368; called by muse, mutect2, varscan2
- ARSI | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as rs199522076, COSV60817762; called by muse, mutect2, varscan2
- FAT1 | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV71671761, COSV71675565; called by muse, mutect2
- H4C9 | c.192G>C p.E64D | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as COSV62889809; called by muse, mutect2, varscan2
- IGHV2-70 | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs532230117; called by muse, varscan2
- IGLV3-1 | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs142180628; called by muse, mutect2, varscan2
- MAX | c.178C>G p.R60G | Missense Mutation (SNP) | VAF 100/117 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM122946, COSV52415839; called by muse, mutect2, varscan2
- PPP1R1B | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 77/155 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1405677322, COSV54202541; called by muse, mutect2, varscan2
- SCUBE2 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.492); catalogued as COSV58542781; called by muse, mutect2
- SLC47A2 | c.225+1G>A p.X75_splice | Splice Site (SNP) | VAF 18/36 reads (50%) | catalogued as rs745786242; called by muse, mutect2, varscan2
- TAF6 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs757585206; called by muse, mutect2, varscan2
- TDRD1 | c.3282T>G p.N1094K | Missense Mutation (SNP) | VAF 6/141 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99315475; called by muse, mutect2
- TRMT44 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV67665098; called by muse, mutect2, varscan2
- UGT8 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1043347555; called by muse, mutect2, varscan2
- ADGRF3 | c.2344A>G p.I782V (on ENST00000311519 / NM_001145168.1; = p.I583V on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/238 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.557); called by muse, mutect2
- ANGEL2 | c.1229A>G p.E410G | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ANKRD30A | c.284_285del p.R95Kfs*5 (on ENST00000611781; = p.R39Kfs*5 on NM_052997.2) | Frame Shift Del (DEL) | VAF 56/160 reads (35%) | called by mutect2, pindel, varscan2
- BAHCC1 | c.6187G>C p.A2063P | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- COL21A1 | c.1515A>T p.K505N | Missense Mutation (SNP) | VAF 62/117 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- CSMD2 | c.9982G>A p.D3328N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- CTNND1 | c.1978T>C p.F660L (on ENST00000399050 / NM_001085458.2; = p.F654L on NM_001331.3) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2
- DEFB129 | c.54C>A p.N18K | Missense Mutation (SNP) | VAF 9/298 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.236); called by muse, mutect2
- FLNB | c.94T>A p.C32S | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- FLT4 | c.2861C>T p.P954L | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GAS2L1 | c.2028G>C p.E676D | Missense Mutation (SNP) | VAF 57/274 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GBE1 | c.856G>C p.D286H | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV1-69D | c.162C>G p.S54R | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by mutect2, varscan2
- KIF13A | c.301T>A p.Y101N | Missense Mutation (SNP) | VAF 80/182 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LBX1 | c.7T>G p.S3A | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- LTN1 | c.2125G>T p.D709Y | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MTCL1 | c.5422T>A p.S1808T (on ENST00000306329 / NM_001378206.1; = p.S1489T on NM_015210.4) | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- MYO1B | c.3124C>G p.Q1042E (on ENST00000304164; = p.Q984E on NM_012223.5) | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- NLRC3 | c.510C>G p.D170E | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.176); called by muse, mutect2
- NPSR1 | c.736A>C p.T246P | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- NUTM2G | c.617del p.V206Afs*46 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel, varscan2
- NYNRIN | c.3364C>T p.L1122F | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PEG3 | c.527C>A p.P176Q | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- PGPEP1 | c.413T>A p.V138E | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- PPARD | c.1180T>G p.Y394D | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- PRR36 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 56/223 reads (25%) | SIFT tolerated, low confidence (0.11); called by muse, mutect2, varscan2
- RABEP1 | c.2242T>A p.L748I | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2
- RFX6 | c.868T>A p.F290I | Missense Mutation (SNP) | VAF 58/92 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- SART3 | c.1731A>T p.L577F (on ENST00000228284; = p.L559F on NM_014706.4) | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCT | c.269T>C p.M90T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- SLC30A4 | c.653T>G p.M218R | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPANXN1 | c.41A>T p.K14M | Missense Mutation (SNP) | VAF 221/229 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPRTN | c.880G>A p.V294I | Missense Mutation (SNP) | VAF 189/408 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- SUSD5 | c.1495dup p.T499Nfs*10 | Frame Shift Ins (INS) | VAF 10/89 reads (11%) | called by mutect2, pindel, varscan2
- SVIL | c.4264A>C p.S1422R (on ENST00000355867 / NM_021738.3; = p.S996R on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- TAS2R1 | c.849A>T p.K283N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TENT5C | c.334_335insAAG p.V111_V112insE | In Frame Ins (INS) | VAF 47/105 reads (45%) | called by mutect2, pindel, varscan2
- TIGD5 | c.770G>T p.G257V | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- TRAF3 | c.1258T>C p.W420R | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAF3 | c.1418T>C p.L473P | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRAF3 | c.1420T>G p.F474V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRGV5 | c.140A>G p.N47S | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRPM7 | c.2894A>G p.Y965C | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, varscan2
- ZCCHC2 | c.1094A>G p.K365R | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZMYND8 | c.28C>G p.P10A (on ENST00000311275 / NM_001363741.2; = p.P30A on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF319 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- ALPI | c.258G>A p.T86= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as rs142586150; called by muse, mutect2, varscan2
- AMMECR1L | c.663C>T p.F221= | Silent (SNP) | VAF 65/322 reads (20%) | catalogued as COSV55760299; called by muse, mutect2, varscan2
- ARHGEF17 | c.1764G>A p.Q588= | Silent (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2, varscan2
- CCL7 | c.24G>C p.L8= | Silent (SNP) | VAF 34/338 reads (10%) | called by muse, mutect2
- CDK5RAP2 | c.3426C>T p.A1142= | Silent (SNP) | VAF 64/136 reads (47%) | called by muse, mutect2, varscan2
- FARP2 | c.1359C>T p.P453= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as rs1039804494; called by muse, mutect2, varscan2
- LVRN | c.522G>A p.V174= | Silent (SNP) | VAF 44/81 reads (54%) | called by muse, mutect2, varscan2
- NALCN | c.684C>T p.H228= | Silent (SNP) | VAF 37/42 reads (88%) | catalogued as COSV51949435; called by muse, mutect2, varscan2
- PEAK1 | c.4491C>T p.L1497= | Silent (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- RIOK1 | c.1692G>T p.T564= | Silent (SNP) | VAF 172/393 reads (44%) | called by muse, mutect2, varscan2
- SCYL3 | c.1062G>A p.R354= | Silent (SNP) | VAF 16/89 reads (18%) | called by muse, mutect2, varscan2
- SLC22A16 | c.1440C>T p.S480= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs145203259, COSV57932732; called by muse, mutect2, varscan2
- SUN2 | c.2097C>T p.G699= | Silent (SNP) | VAF 21/100 reads (21%) | called by muse, mutect2, varscan2
- UBE2QL1 | c.276C>G p.L92= | Silent (SNP) | VAF 9/153 reads (6%) | catalogued as rs1414039566; called by muse, mutect2
- AC021218.1 | n.1389T>A | RNA (SNP) | VAF 52/114 reads (46%) | called by muse, mutect2, varscan2
- ACACB | c.5022+431T>C | Intron (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- ADAMTSL3 | c.*791T>A | 3'UTR (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- ARHGAP17 | c.1491-106_1491-105del | Intron (DEL) | VAF 23/51 reads (45%) | called by mutect2, pindel, varscan2
- C1orf21 | c.*2610T>C | 3'UTR (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- CACNA1B | c.*1992G>T | 3'UTR (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- CAMK1D | c.299+41C>T | Intron (SNP) | VAF 64/121 reads (53%) | called by muse, mutect2, varscan2
- CC2D2A | c.247+400G>A | Intron (SNP) | VAF 21/44 reads (48%) | catalogued as rs1011059334; called by muse, mutect2
- CCDC102B | c.1263+200A>G | Intron (SNP) | VAF 84/168 reads (50%) | called by muse, mutect2, varscan2
- CEP43 | c.212-54A>T | Intron (SNP) | VAF 8/29 reads (28%) | catalogued as rs1427524394; called by muse, mutect2
- CFAP77 | c.*712G>A | 3'UTR (SNP) | VAF 54/124 reads (44%) | called by muse, mutect2, varscan2
- CGNL1 | c.*1253G>C | 3'UTR (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- CHST10 | c.*111C>T | 3'UTR (SNP) | VAF 33/65 reads (51%) | catalogued as rs921342850, COSV99959054; called by muse, mutect2, varscan2
- CIT | c.*1499G>A | 3'UTR (SNP) | VAF 46/97 reads (47%) | called by muse, mutect2, varscan2
- COL1A2 | c.2566-26A>C | Intron (SNP) | VAF 25/51 reads (49%) | called by muse, mutect2, varscan2
- COPS7B | c.*581T>G | 3'UTR (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- CSMD3 | c.*423G>T | 3'UTR (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- CYFIP1 | chr15:22867462 T>A | 3'Flank (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- DOCK3 | c.*1039G>A | 3'UTR (SNP) | VAF 7/131 reads (5%) | called by muse, mutect2
- DPF2 | c.*718C>T | 3'UTR (SNP) | VAF 104/223 reads (47%) | called by muse, mutect2, varscan2
- DPP10 | c.61-147388C>T | Intron (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- DTX3L | c.*1917T>G | 3'UTR (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- EIF3D | c.991-9T>A | Intron (SNP) | VAF 73/293 reads (25%) | called by muse, mutect2, varscan2
- ERBB4 | c.*3610T>C | 3'UTR (SNP) | VAF 68/160 reads (43%) | called by muse, mutect2, varscan2
- GAPVD1 | c.1441+1249A>T | Intron (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- HIVEP1 | c.40+22437T>A | Intron (SNP) | VAF 43/82 reads (52%) | called by muse, mutect2, varscan2
- HS3ST1 | c.-44G>A | 5'UTR (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- HSPA4 | c.*512C>A | 3'UTR (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- KDR | c.*375A>G | 3'UTR (SNP) | VAF 71/154 reads (46%) | called by muse, mutect2, varscan2
- LAMP2 | c.1093+3173T>A | Intron (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- LRRC58 | c.*1600C>T | 3'UTR (SNP) | VAF 7/102 reads (7%) | called by muse, mutect2
- MAPKAPK5 | chr12:111842130 G>A | 5'Flank (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- MDM4 | c.*2545T>C | 3'UTR (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- MGAT1 | c.*277T>G | 3'UTR (SNP) | VAF 7/119 reads (6%) | called by muse, mutect2
- NCKIPSD | c.*71T>A | 3'UTR (SNP) | VAF 56/116 reads (48%) | called by muse, mutect2, varscan2
- NSD2 | c.2137+530G>T | Intron (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*9401C>T | 3'UTR (SNP) | VAF 14/165 reads (8%) | called by muse, mutect2
- OR2J3 | c.-29T>A | 5'UTR (SNP) | VAF 63/158 reads (40%) | catalogued as COSV65848950; called by muse, mutect2, varscan2
- OR8G5 | c.*6A>C | 3'UTR (SNP) | VAF 60/142 reads (42%) | called by muse, mutect2, varscan2
- PIM1 | c.*644T>G | 3'UTR (SNP) | VAF 30/91 reads (33%) | called by muse, mutect2, varscan2
- PLAC8 | c.*9+303del | Intron (DEL) | VAF 21/127 reads (17%) | called by mutect2, pindel, varscan2
- POU6F2 | chr7:39467765 ins A | 3'Flank (INS) | VAF 16/138 reads (12%) | catalogued as rs977067484; called by mutect2, varscan2
- PSMA2 | c.375-24T>A | Intron (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- PUM2 | c.*2111T>C | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- RAPGEF5 | c.871-108A>C | Intron (SNP) | VAF 20/221 reads (9%) | called by muse, mutect2
- SIGMAR1 | c.*906T>C | 3'UTR (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- SIRT5 | c.*243A>G | 3'UTR (SNP) | VAF 58/124 reads (47%) | called by muse, mutect2, varscan2
- SIRT5 | c.*244T>A | 3'UTR (SNP) | VAF 57/123 reads (46%) | called by muse, mutect2, varscan2
- SLC24A4 | c.*1197G>A | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- SLC9B2 | c.*2+983G>A | Intron (SNP) | VAF 10/38 reads (26%) | catalogued as rs1266148131; called by muse, mutect2, varscan2
- SPG11 | c.6007-33A>C | Intron (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- SPRY3 | c.*892T>G | 3'UTR (SNP) | VAF 88/246 reads (36%) | called by muse, mutect2, varscan2
- STK17B | c.*157C>G | 3'UTR (SNP) | VAF 47/101 reads (47%) | called by muse, mutect2, varscan2
- STK25 | c.-40C>A | 5'UTR (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- SUSD6 | c.*2043G>C | 3'UTR (SNP) | VAF 17/28 reads (61%) | called by muse, mutect2, varscan2
- SYCE1L | c.*110A>G | 3'UTR (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- USP25 | chr21:15879374 G>A | 3'Flank (SNP) | VAF 7/10 reads (70%) | called by muse, mutect2, varscan2
- VASH1 | c.*3077G>C | 3'UTR (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- VSTM2A | c.634+1246T>A | Intron (SNP) | VAF 43/88 reads (49%) | called by muse, mutect2, varscan2
- VTI1A | c.264+38T>G | Intron (SNP) | VAF 28/146 reads (19%) | called by muse, mutect2
- ZMAT4 | c.*467G>A | 3'UTR (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- ZRANB2 | c.-18G>A | 5'UTR (SNP) | VAF 35/134 reads (26%) | catalogued as rs770754395, COSV99639243; called by muse, mutect2, varscan2
